Gene-level copy-number profile of tumor specimen TCGA-VT-A80J-02A from TCGA case TCGA-VT-A80J, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 49.1 years (17,925 days).
Specimen TCGA-VT-A80J-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.d77becc0-4c18-4206-a4a7-66c80020520b.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 3,894 have no estimate.
https://portal.gdc.cancer.gov/files/22235c9d-35ac-4e2d-906a-55b6047e78ea

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 52; copy number 1: 3,390; copy number 2: 17,253; copy number 3: 25,162; copy number 4: 8,667; copy number 5: 541; copy number 6: 538; copy number 7: 1,126.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VT-A80J-02A-11D-A416-01): tumor purity 0.8, ploidy 2.82, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:241,881,363–242,084,233, 6 genes: LINC01237, LINC01238, AC093642.3, AC093642.1, AC093642.6, LINC01880.
- chr9:21,524,307–26,118,408, 44 genes: SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1.
- chr11:133,064,697–133,302,634, 2 genes: AP004782.1, AP003972.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,126 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:53,180,921–53,246,482, 7 genes, copy number 7 (within-gene range 4–7): AL606760.4, CPT2, AL606760.2, CZIB, AL606760.3, MAGOH, AL606760.1.
- chr3:83,924,157–89,590,097, 46 genes, copy number 7: AC092825.1, SRRM1P2, AC117464.1, LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6.
- chr3:180,989,762–198,080,720, 397 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:91,880,791–100,272,218, 202 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr7:100,319,222–112,206,407, 241 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr15:23,562,062–24,090,821, 8 genes, copy number 7: MIR4508, MKRN3, AC126407.1, MAGEL2, NDN, AC087490.1, RNU6-741P, PWRN4.
- chr15:24,162,754–24,225,854, 2 genes, copy number 7: PWRN2, AC087463.1.
- chr15:24,978,583–25,420,336, 1 gene, copy number 7 (within-gene range 6–7): SNHG14.
- chr15:25,189,414–26,053,123, 52 genes, copy number 7: SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1, SNORD115-45, SNORD115-46, SNORD115-47, SNORD115-48, SNORD109B, UBE3A, AC100774.1, LINC02250, AC023449.1, ATP10A, RNA5SP390, MIR4715, AC016266.1, LINC02346, AC044913.2, AC044913.1, AC100836.1.
- chr19:30,850,975–35,353,862, 139 genes, copy number 7 (broad region; genes not listed).
- chr19:56,669,941–57,398,584, 31 genes, copy number 7 (within-gene range 2–7): AC006115.2, OR5AH1P, ZIM2, AC006115.1, PEG3, MIMT1, AC004792.1, AC044792.1, RPL7AP69, AC025588.4, USP29, ZIM3, AC025588.2, AC025588.3, DUXA, AC025588.1, ZNF264, AURKC, ZNF805, AC005261.3, ZNF460-AS1, ZNF460, AC005261.5, AC005261.1, AC005261.4, ZNF543, AC005261.2, ZNF304, ZNF547, TRAPPC2B, AC003002.1.

Autosomal genes at a single copy (total copy number 1): 3,390. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
